Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A90W, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Barretos Cancer Hospital, specimen TCGA-YU-A90W-01A (Primary Tumor).

Collect date: _____
(MM/DD/YYYY)

ICD-O-3
Seminoma NOS 9061/3
Site (R) Testis NOS C62.9
g/u 2/8/14

PATHOLOGY REPORT:

PRIMARY SITE: Right testis

1. "Right testis":

- Seminoma compromising all testicular parenchyma, measuring 7.7cm in longest axis.
- Rete testis focally compromised by the neoplasia.
- Epididymis and spermatic cord uninvolved by neoplasia.
- Angiolymphatic invasion: not detected.
- Perineural invasion: not detected.
- Necrosis: absent.
- Surgical margins uninvolved by neoplasia.

Primary Tumor Discrepancy		✓

Source: NCI Genomic Data Commons file 7c89471e-13f5-4143-b899-c76eb75eaeea (TCGA-YU-A90W.7685DF84-BB71-4D7F-939D-1F3BD38CEFDA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).